Surgical pathology report (de-identified scan), TCGA case TCGA-95-7043, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Washington University - Emory, specimen TCGA-95-7043-01A (Primary Tumor).

[page 1 of 4]
This information is subject to all Federal and State laws regarding confidentiality and privacy and to the policies and procedures of patient information. Any unauthorized use, disclosure, or reproduction of this information is strictly prohibited.

Anat Path Reports

* Final Report *

Document Type:
Document Date:
Document Status:
Document Title:
Encounter info:

* Final Report *

APRPT (Verified)

Patient Name:

MRN:

Location:

Client:

Submitting

Phys:

Final Surgical Pathology Report

Final Pathologic Diagnosis

A. LUNG, RIGHT UPPER LOBE, WEDGE RESECTION, A1FS:

- ADENOCARCINOMA, MIXED SUBTYPE WITH SOLID AND ACINAR PATTERNS OF GROWTH, POORLY DIFFERENTIATED.
- THE TUMOR MEASURES 1.5 X 1.3 X 1.1 CM.
- ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- FOCI OF TUMOR EXTEND TO THE INKED EDGE (SEE COMMENT).
- NO VISCERAL PLEURAL INVASION IS IDENTIFIED.
- NO PERINEURAL INVASION IS IDENTIFIED.
- MARKED EMPHYSEMATOUS CHANGES AND CARCINOID TUMORLETS.
- SEE SYNOPTIC, COMMENT.

B. LUNG, RIGHT LOWER LOBE, WEDGE RESECTION, B1FS:

- ADENOCARCINOMA, MIXED SUBTYPE WITH MICROPAPILLARY, ACINAR AND LEPIDIC PATTERNS OF GROWTH, MODERATELY DIFFERENTIATED.
- THE TUMOR MEASURES 0.7 X 0.6 X 0.5 CM.
- ANGIOLYMPHATIC INVASION IS IDENTIFIED.

Printed by:

Printed on:

Page 1 of 4
(Continued)

[page 2 of 4]
Anat Path Reports

* Final Report *

- FOCI OF TUMOR EXTEND TO THE INKED EDGE (SEE COMMENT).
- NO VISCERAL PLEURAL INVASION IS IDENTIFIED.
- NO PERINEURAL INVASION IS IDENTIFIED.
- MARKED EMPHYSEMATOUS CHANGES.
- SEE SYNOPTIC, COMMENT.

Comment

Immunohistochemical stain results (performed on both part A and B):

	PART A	PART B
CK7 -----	positive	positive
CK20 -----	negative	positive
TTF1 -----	positive	positive
Napsin -----	positive	positive

The immunoprofiles for the tumors in part A and B are compatible with a lung primary (CK7, TTF, Napsin positive). However, the differences in histologic patterns of growth and CK20 immunoprofile are suggestive of two separate primary adenocarcinomas of the lung. If the tumors are determined to be separate primaries, each would be staged as pT1a. The edge of resection is inked after the staple line has been removed in both specimens and therefore the inked edge may not represent the true margin of resection. Clinical correlation is recommended.

ANALYTE SPECIFIC REAGENT (ASR) DISCLAIMER:

Some of the above tests may use [REDACTED]. These tests were developed and their performance characteristics determined by [REDACTED]. They have not been cleared or approved by the Federal Drug Administration (FDA). The FDA does not require these tests to go through premarket FDA review. These tests are used for clinical purposes, and should not be regarded as investigational or for research. [REDACTED] is certified under the Clinical Laboratory Improvement Amendments (CLIA) as qualified to perform high complexity clinical laboratory testing.

Synoptic Worksheet

A. Right upper and lower lobes:

Specimen:	Lobe(s) of lung: Right upper and lower lobes
Procedure:	Wedge resection
Specimen Integrity:	Indeterminate
Specimen Laterality:	Right
Tumor Site:	Upper lobe
	Lower lobe
Tumor Focality:	Separate tumor nodules in different lobes, sites: upper and lower

Printed by:
Printed on:

Page 2 of 4
(Continued)

[page 3 of 4]
Anat Path Reports

* Final Report *

Histologic Type:	Adenocarcinoma, mixed subtype
Histologic Grade:	Other: see parts A and B.
Tumor Size:	Greatest dimension: 1.5 cm Additional dimension: 1.3 cm Additional dimension: 1.1 cm
Visceral Pleura Invasion:	Not identified
Tumor Extension:	Not applicable
Bronchial Margin:	Involvement by invasive carcinoma not applicable Involvement by squamous cell carcinoma in situ (CIS) not applicable
Vascular Margin:	Not applicable
Parenchymal Margin:	Not applicable
Parietal Pleural Margin:	Not applicable
Chest Wall Margin:	Not applicable
Other Attached Tissue Margin:	Not applicable
Treatment Effect:	Not applicable
Lymph-Vascular Invasion:	Present
Extranodal Extension:	Not identified
TNM Descriptors:	Not applicable
Primary Tumor (pT):	pTX: Primary tumor cannot be assessed, or tumor proven by presence of malignant cells in sputum or bronchial washings but not visualized by imaging or bronchoscopy
Regional Lymph Nodes (pN):	pNX: Regional lymph nodes cannot be assessed Nodes examined: 0 Nodes involved: 0
Distant Metastasis (pM):	Not applicable
Additional Pathologic Findings:	Emphysema
Comments	See final diagnosis comment regarding pT stage.

Clinical History

Right VATS. Tobacco 40 pack year/COPD. RLL lung.

Specimen(s) Received

A: Right upper and lower lobes

B: Right lower lung lobe wedge

Gross Description

Specimen A is received fresh for intraoperative consultation and is labeled with the patient's name, medical record number and as "right upper lung wedge." The specimen consists of a lung wedge measuring 8.0 x 4.2 x 2.5 cm and weighing 16 grams. One firm, white nodule is found measuring 1.5 x 1.3 x 1.1 cm. A representative section of this nodule is submitted for frozen section diagnosis and the cryoblock is transferred into cassette "A1FS." The parenchymal edge is inked green after the staple line has been removed. The uninvolved lung shows emphysematous changes. Representative sections are submitted as follows:

A1FS: Representative nodule

Printed by:

Printed on:

Page 3 of 4
(Continued)

[page 4 of 4]
Anat Path Reports

* Final Report *

A2-A5: Representative nodule
A6: Normal lung

Specimen B is received fresh for intraoperative consultation and is labeled with the patient's name, medical record number and as "right lower lobe lung wedge." The specimen consists of a lung wedge measuring 8.0 x 1.3 x 1.2 cm and weighing 4.3 grams. There is a stapled resection margin lined at one end of the specimen. A small white nodule is identified which measures 0.7 x 0.6 x 0.5 cm. The nodule abuts the resection edge. The resection edge is inked green after the staple line has been removed. A representative section of the nodule is submitted for frozen section diagnosis and the cryoblock is transferred to cassette "B1FS." No definite residual nodule is identified after frozen section. Sections are submitted as follows:
B1FS: Representative nodule
B2-B6: Specimen submitted entirely

Intraoperative Consult Diagnosis

A1FS: LUNG, RIGHT UPPER LOBE (FROZEN SECTION): ADENOCARCINOMA.

Frozen section results were communicated to the surgical team and were repeated back by

B1FS: LUNG, RIGHT LOWER LOBE (FROZEN SECTION): ADENOCARCINOMA.

Frozen section results were communicated to the surgical team and were repeated back by

Pathologist:

Microscopic Description

Microscopic examination is performed.

Printed by:
Printed on:

Source: NCI Genomic Data Commons file 3bebccb4-5e54-4a83-925e-f0567b3124d1 (TCGA-95-7043.A30ED7EC-19A9-4D15-B405-86132271A652.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).